FM case AD13113 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach.
https://portal.gdc.cancer.gov/cases/95ef74a1-10a5-41c2-92a4-418c0312e09f

Male, 62.1 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the stomach; metastasis. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Metastatic.
